Somatic mutation profile of tumor specimen TCGA-CJ-5672-01A (aliquot TCGA-CJ-5672-01A-11D-1534-10) from TCGA case TCGA-CJ-5672, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-CJ-5672-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7de6b0b-1c9b-497a-b606-eb99bccb97e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-5672-11A (Solid Tissue Normal), aliquot TCGA-CJ-5672-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2f44e25-7256-475e-a390-27b3efbe264d

The open-access MAF lists 107 somatic variants for this specimen: 82 protein-altering or splice-affecting, 20 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 20, Frame Shift Del 9, Nonsense Mutation 6, Intron 2, Nonstop Mutation 2, In Frame Del 2, Splice Site 1, 5'Flank 1, Frame Shift Ins 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.641G>T p.*214Lext*14 | Nonstop Mutation (SNP) | VAF 19/55 reads (35%) | catalogued as rs869025668, CM112802, COSV56555598; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACER1 | c.440A>T p.N147I | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56836062; called by muse, mutect2, varscan2
- APAF1 | c.3191A>G p.D1064G (on ENST00000551964 / NM_181861.2; = p.D1010G on NM_001160.3) | Missense Mutation (SNP) | VAF 34/578 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV59665895; called by muse, mutect2
- APOO | c.551A>T p.N184I | Missense Mutation (SNP) | VAF 261/479 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV64870890; called by muse, mutect2, varscan2
- BBS12 | c.1930A>C p.N644H | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.766); catalogued as rs1336021784, COSV58562483; called by muse, mutect2, varscan2
- BSCL2 | c.127T>A p.W43R | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53655306; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1337T>A p.F446Y (on ENST00000357886 / NM_001365728.1; = p.F432Y on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59427844; called by muse, mutect2, varscan2
- CFAP65 | c.2418G>T p.K806N | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV58563518; called by muse, mutect2, varscan2
- CFH | c.1660G>A p.G554S | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.641); catalogued as COSV66410662; called by muse, mutect2, varscan2
- CFTR | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.271); catalogued as COSV50071070; called by muse, mutect2, varscan2
- CNNM4 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 88/223 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV65661504; called by muse, mutect2, varscan2
- COL5A3 | c.3611A>T p.K1204M | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53414502; called by muse, mutect2, varscan2
- COX17 | c.191G>T p.*64Lext*8 | Nonstop Mutation (SNP) | VAF 130/530 reads (25%) | catalogued as COSV53761096; called by muse, mutect2, varscan2
- CYBRD1 | c.262G>C p.G88R | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100361438; called by muse, mutect2
- DENND4A | c.1166G>A p.S389N | Missense Mutation (SNP) | VAF 122/423 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV71265691, COSV71266535; called by muse, varscan2
- DMRTA1 | c.678G>T p.E226D | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.078); catalogued as COSV57924721; called by muse, mutect2, varscan2
- DNAH2 | c.10876T>A p.C3626S | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV66722348; called by muse, mutect2, varscan2
- EYA4 | c.1718C>T p.A573V (on ENST00000531901 / NM_001301013.1; = p.A567V on NM_004100.5) | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62056681; called by muse, mutect2, varscan2
- FLT1 | c.2473G>T p.E825* | Nonsense Mutation (SNP) | VAF 44/356 reads (12%) | catalogued as COSV56734033; called by muse, mutect2, varscan2
- FNDC7 | c.2170G>A p.V724M | Missense Mutation (SNP) | VAF 224/912 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV54755834; called by muse, varscan2
- FRAS1 | c.3672A>T p.E1224D | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.724); catalogued as COSV53626720; called by muse, mutect2, varscan2
- GKN2 | c.97G>T p.G33C | Missense Mutation (SNP) | VAF 77/633 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61031303, COSV61031557; called by muse, mutect2, varscan2
- GSN | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV57999321; called by muse, mutect2, varscan2
- GTF3C2 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 139/329 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV53127722; called by muse, mutect2, varscan2
- HAUS7 | c.857A>G p.Y286C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV57850058; called by muse, mutect2, varscan2
- HECW2 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV53665989; called by muse, mutect2, varscan2
- HS3ST5 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.959); catalogued as rs144143119; called by muse, mutect2, varscan2
- IL16 | c.401G>T p.R134M | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV57265885; called by muse, mutect2, varscan2
- ITIH5 | c.302T>G p.L101R | Missense Mutation (SNP) | VAF 215/805 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV56909018; called by muse, mutect2, varscan2
- KCNA4 | c.15G>T p.M5I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV60253974; called by muse, mutect2, varscan2
- KCNAB1 | c.358-1G>T p.X120_splice (on ENST00000490337 / NM_172160.3; = p.X109_splice on NM_003471.3) | Splice Site (SNP) | VAF 64/244 reads (26%) | catalogued as COSV56749124; called by muse, mutect2, varscan2
- MAGEA11 | c.397C>A p.L133M | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as COSV60757186; called by muse, mutect2, varscan2
- MAP3K5 | c.2762C>G p.P921R | Missense Mutation (SNP) | VAF 48/364 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62890345; called by muse, mutect2
- MECOM | c.1408G>T p.V470L (on ENST00000468789 / NM_001105078.4; = p.V658L on NM_004991.4) | Missense Mutation (SNP) | VAF 235/884 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV52968941; called by muse, mutect2, varscan2
- MED13L | c.3496G>T p.A1166S | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV56124485; called by muse, mutect2, varscan2
- NLRP13 | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1461669585, COSV61622926; called by muse, mutect2, varscan2
- OR10S1 | c.413T>A p.L138Q | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV73342896; called by muse, mutect2
- OR4C3 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as COSV100167551, COSV60587955; called by muse, mutect2, varscan2
- OR8J3 | c.543T>G p.I181M | Missense Mutation (SNP) | VAF 135/496 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV56882529; called by muse, mutect2, varscan2
- P3H4 | c.623T>A p.F208Y | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58637781; called by muse, mutect2, varscan2
- PAGE3 | c.311C>G p.P104R | Missense Mutation (SNP) | VAF 88/170 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as COSV100892018, COSV66587113; called by muse, mutect2
- PCDHB3 | c.1078T>G p.S360A | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.026); catalogued as COSV50593313; called by muse, mutect2, varscan2
- PDHB | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as rs1019990431, COSV57057230; called by muse, mutect2, varscan2
- PHF20 | c.1107G>T p.Q369H | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as COSV59187259; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50252733; called by muse, varscan2
- RAB1A | c.385A>G p.T129A | Missense Mutation (SNP) | VAF 99/492 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV53126041; called by muse, mutect2, varscan2
- RARB | c.1160T>C p.I387T (on ENST00000383772 / NM_001290216.2; = p.I380T on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV51974373; called by muse, mutect2, varscan2
- RNF121 | c.895C>A p.L299M | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV52621841; called by muse, mutect2, varscan2
- RNF43 | c.1595C>T p.S532F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1346057375, COSV68459086; called by muse, mutect2, varscan2
- SATB2 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 18/236 reads (8%) | catalogued as COSV53477435, COSV53488446; called by muse, mutect2
- SCYL2 | c.2261T>C p.I754T | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV62569648; called by muse, mutect2, varscan2
- SF3B1 | c.3620C>T p.S1207L | Missense Mutation (SNP) | VAF 69/388 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV59205823; called by muse, mutect2, varscan2
- SIN3B | c.1821G>T p.Q607H | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56134649; called by muse, mutect2, varscan2
- SORBS2 | c.818G>A p.S273N (on ENST00000284776 / NM_021069.5; = p.S366N on NM_003603.6) | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53006829; called by muse, mutect2, varscan2
- SP4 | c.1030A>G p.T344A | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV56024649; called by muse, mutect2, varscan2
- SVEP1 | c.755T>C p.F252S | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57041466; called by muse, mutect2, varscan2
- TAF1 | c.2018A>G p.Q673R (on ENST00000373790 / NM_138923.4; = p.Q694R on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/154 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760871346, COSV52118865; called by muse, mutect2
- TM7SF3 | c.246G>A p.P82= | Splice Region (SNP) | VAF 76/329 reads (23%) | catalogued as rs751674880, COSV58003159; called by muse, varscan2
- TMEM102 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.081); catalogued as COSV53440446; called by muse, mutect2, varscan2
- TMEM199 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 19/241 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs544772600, COSV50228615; called by muse, mutect2
- TXNDC5 | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 37/133 reads (28%) | catalogued as rs759950578, COSV51664800, COSV51672705; called by muse, mutect2, varscan2
- USP9Y | c.1246A>T p.K416* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV59099910; called by muse, mutect2, varscan2
- VARS1 | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65155444; called by muse, mutect2, varscan2
- VIRMA | c.2494T>C p.Y832H | Missense Mutation (SNP) | VAF 57/103 reads (55%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV52587894; called by muse, mutect2, varscan2
- VIRMA | c.1727A>C p.K576T | Missense Mutation (SNP) | VAF 126/240 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as COSV52587910; called by muse, mutect2
- ZMYM1 | c.2402A>C p.K801T | Missense Mutation (SNP) | VAF 51/382 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.254); catalogued as COSV63252551; called by muse, mutect2, varscan2
- ZNF354B | c.299A>T p.Q100L | Missense Mutation (SNP) | VAF 124/261 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as COSV59366790; called by muse, mutect2, varscan2
- ZNF57 | c.432G>C p.K144N | Missense Mutation (SNP) | VAF 70/213 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.485); catalogued as rs760184967, COSV60984006; called by muse, mutect2, varscan2
- AP1B1 | c.15del p.K5Nfs*14 | Frame Shift Del (DEL) | VAF 80/706 reads (11%) | called by mutect2, varscan2
- ATP10D | c.1352_1367del p.R451Qfs*28 | Frame Shift Del (DEL) | VAF 13/93 reads (14%) | called by mutect2, pindel, varscan2
- EDC4 | c.811del p.M271Cfs*23 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | called by mutect2, varscan2
- GGNBP2 | c.1060C>T p.Q354* | Nonsense Mutation (SNP) | VAF 42/618 reads (7%) | called by muse, mutect2
- GRM3 | c.231_250del p.D77Efs*39 | Frame Shift Del (DEL) | VAF 46/135 reads (34%) | called by mutect2, pindel*, varscan2*
- KLRC2 | c.518_519dup p.G174Lfs*13 | Frame Shift Ins (INS) | VAF 122/236 reads (52%) | called by mutect2, varscan2
- MCOLN1 | c.146del p.F49Sfs*2 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- NUMB | c.401_403del p.G134_T135delinsA (on ENST00000355058; = p.G123_T124delinsA on NM_003744.5) | In Frame Del (DEL) | VAF 23/164 reads (14%) | called by mutect2, pindel, varscan2
- RNF128 | c.454del p.R152Afs*13 | Frame Shift Del (DEL) | VAF 11/24 reads (46%) | called by mutect2, pindel, varscan2
- ROCK1 | c.1682_1688del p.A561Dfs*2 | Frame Shift Del (DEL) | VAF 42/320 reads (13%) | called by mutect2, pindel, varscan2
- SPIDR | c.317G>A p.S106N | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- U2AF2 | c.1303_1305del p.E435del | In Frame Del (DEL) | VAF 20/82 reads (24%) | called by mutect2, pindel, varscan2
- VSIG8 | c.180_183del p.E61Gfs*53 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | called by mutect2, pindel, varscan2
- YLPM1 | c.6044del p.D2015Vfs*40 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | called by mutect2, pindel, varscan2
- ADAMTS18 | c.2304C>T p.V768= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV51419003, COSV99272774; called by muse, mutect2, varscan2
- BCL2L12 | c.108G>T p.P36= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs756293294, COSV55863763; called by muse, mutect2, varscan2
- CD163 | c.2068C>T p.L690= | Silent (SNP) | VAF 12/163 reads (7%) | catalogued as COSV63134898; called by muse, mutect2
- CTNNA1 | c.1876A>C p.R626= | Silent (SNP) | VAF 17/139 reads (12%) | catalogued as COSV57077540; called by muse, mutect2
- ESF1 | c.1434T>C p.D478= | Silent (SNP) | VAF 141/552 reads (26%) | catalogued as rs1306878234, COSV52522563; called by muse, mutect2
- GPT2 | c.1281C>T p.V427= | Silent (SNP) | VAF 23/205 reads (11%) | catalogued as COSV60839383; called by muse, mutect2, varscan2
- LRRC7 | c.4209T>C p.P1403= (on ENST00000651989 / NM_001370785.2; = p.P1323= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 27/135 reads (20%) | catalogued as COSV50512021; called by muse, mutect2, varscan2
- LYST | c.2661G>A p.K887= | Silent (SNP) | VAF 56/196 reads (29%) | catalogued as COSV67710207; called by muse, mutect2, varscan2
- MYG1 | c.720G>A p.L240= | Silent (SNP) | VAF 58/197 reads (29%) | catalogued as COSV52933553; called by muse, mutect2, varscan2
- NAT8 | c.153C>T p.L51= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as rs750141183, COSV55542777; called by muse, mutect2, varscan2
- NRP2 | c.255T>C p.Y85= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV55931387; called by muse, varscan2
- OGDH | c.114G>T p.R38= | Silent (SNP) | VAF 34/252 reads (13%) | catalogued as COSV56053386; called by muse, mutect2, varscan2
- PCNT | c.7854G>A p.Q2618= | Silent (SNP) | VAF 34/107 reads (32%) | catalogued as COSV64030515, COSV64031295; called by muse, mutect2, varscan2
- RFT1 | c.885A>G p.P295= | Silent (SNP) | VAF 70/221 reads (32%) | catalogued as COSV99965566; called by muse, mutect2
- SLC36A2 | c.1155T>C p.I385= | Silent (SNP) | VAF 56/150 reads (37%) | catalogued as COSV58864107; called by muse, mutect2, varscan2
- SPTBN2 | c.222C>T p.V74= | Silent (SNP) | VAF 49/179 reads (27%) | catalogued as COSV59456403; called by muse, mutect2, varscan2
- TANC1 | c.3696G>A p.E1232= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as rs1219626187, COSV55091902; called by muse, mutect2, varscan2
- VPS35L | c.762G>T p.V254= | Silent (SNP) | VAF 23/232 reads (10%) | catalogued as COSV51986929; called by muse, mutect2, varscan2
- ZFAND2B | c.447C>A p.I149= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as COSV54697970; called by muse, mutect2, varscan2
- ZNF780B | c.2460C>T p.I820= | Silent (SNP) | VAF 47/190 reads (25%) | catalogued as COSV55465846; called by muse, mutect2, varscan2
- AC245047.1 | n.118_126delinsG | RNA (DEL) | VAF 35/153 reads (23%) | called by pindel, varscan2*
- CR1 | c.487+12315C>T | Intron (SNP) | VAF 3/72 reads (4%) | catalogued as COSV100887970; called by muse, mutect2
- CST7 | c.-9del | 5'UTR (DEL) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- MGAM | c.4618+335C>T | Intron (SNP) | VAF 7/83 reads (8%) | catalogued as COSV101527522; called by muse, mutect2
- VPS11 | chr11:119067920 C>G | 5'Flank (SNP) | VAF 11/60 reads (18%) | catalogued as rs1352760161, COSV56186149; called by muse, mutect2, varscan2
